Somatic mutation profile of tumor specimen TCGA-06-6699-01A (aliquot TCGA-06-6699-01A-11D-1845-08) from TCGA case TCGA-06-6699, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.0 years (21,190 days).
Specimen TCGA-06-6699-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bad1338-89ac-406d-837d-2fde1514bde5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6699-10A (Blood Derived Normal), aliquot TCGA-06-6699-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/808c2c8e-3355-4738-8904-d8b83be771cb

The open-access MAF lists 68 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 15, RNA 2, Nonsense Mutation 2, Splice Site 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1708C>T p.R570W (on ENST00000372530 / NM_001198934.2; = p.R527W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376706540, COSV55085131; called by muse, mutect2, varscan2
- CIZ1 | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769302396, COSV52970906; called by mutect2, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- ACE | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 111/251 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.191); catalogued as rs376430907; called by muse, mutect2, varscan2
- ADAM33 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs1295598818, COSV62934552; called by muse, mutect2
- ADAMTS18 | c.2095G>A p.G699S | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs142855321; called by muse, mutect2, varscan2
- CLDN14 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs573588226, COSV59775287; called by muse, mutect2, varscan2
- CLEC4M | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs761150558, COSV50217414; called by muse, mutect2, varscan2
- CPA6 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV52734150; called by muse, mutect2, varscan2
- CSNK1D | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as COSV53925499; called by muse, mutect2, varscan2
- CUX2 | c.3935G>A p.G1312D | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV55625807; called by muse, mutect2
- CYP4F11 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201684723, COSV56127805, COSV99930896; called by muse, mutect2, varscan2
- DTX4 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs765078380, COSV57092163; called by muse, mutect2, varscan2
- FAM153B | c.1063G>A p.E355K (on ENST00000253490; = p.E278K on NM_001265615.1) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.736); catalogued as rs778914514, COSV99498819; called by mutect2, varscan2
- FBN3 | c.7187C>A p.P2396Q | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.793); catalogued as COSV54464740; called by muse, mutect2, varscan2
- FER1L6 | c.5393G>A p.R1798H | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766353103, COSV67550997; called by muse, mutect2, varscan2
- FOXP3 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs2232369, COSV66051616; called by muse, mutect2, varscan2
- FRMPD4 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1194951279, COSV66217798; called by muse, mutect2, varscan2
- IHH | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as rs762916918, COSV55393514; called by muse, mutect2, varscan2
- ISM2 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs201324121, COSV53635766; called by muse, mutect2, varscan2
- ITIH6 | c.3382G>A p.A1128T | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as rs146825535, COSV54490747; called by muse, mutect2, varscan2
- KCNG2 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV60267604; called by muse, mutect2
- KLHL3 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778670860, COSV59053906; called by muse, mutect2, varscan2
- LMBR1 | c.1085C>A p.S362Y | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV62221293; called by muse, varscan2
- MAPK8IP3 | c.2162A>G p.N721S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs375982015; called by muse, mutect2, varscan2
- MAX | c.8A>T p.D3V | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52417892; called by muse, mutect2, varscan2
- MMP13 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.053); catalogued as rs776309041, COSV52824513; called by muse, mutect2, varscan2
- MUC16 | c.31213G>A p.V10405I | Missense Mutation (SNP) | VAF 110/480 reads (23%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs201549151; called by muse, mutect2, varscan2
- MYO15A | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.09); catalogued as COSV52759669; called by muse, mutect2, varscan2
- OCA2 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1280092718, COSV62349722; called by muse, mutect2, varscan2
- OLFM2 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53431644; called by muse, mutect2, varscan2
- OR8G5 | c.690C>A p.Y230* | Nonsense Mutation (SNP) | VAF 85/172 reads (49%) | catalogued as COSV100422279; called by muse, varscan2
- PAK5 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1159424856, COSV62024446; called by muse, mutect2
- PCDHGA4 | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.098); catalogued as rs746353389, COSV53919898, COSV53932137; called by muse, mutect2, varscan2
- PCYT1A | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs549056100, COSV53058092; called by muse, mutect2, varscan2
- PDS5A | c.3815G>A p.R1272H | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.674); catalogued as rs763310762, COSV57827577; called by muse, mutect2, varscan2
- PEAK3 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.473); catalogued as COSV59701697; called by muse, mutect2, varscan2
- PRKN | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.51); catalogued as COSV58238605; called by muse, mutect2, varscan2
- PTPDC1 | c.1355C>A p.T452K (on ENST00000375360 / NM_177995.3; = p.T504K on NM_152422.4) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.394); catalogued as COSV56624248; called by muse, mutect2, varscan2
- PTPRN2 | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV67046189, COSV67060460; called by muse, mutect2, varscan2
- SEMA3E | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401480973, COSV57096745; called by muse, mutect2
- SLC26A5 | c.1233+1G>A p.X411_splice | Splice Site (SNP) | VAF 21/83 reads (25%) | catalogued as COSV59703123; called by muse, mutect2, varscan2
- SOX9 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV55425539; called by mutect2, varscan2
- TEX11 | c.2096C>A p.S699* (on ENST00000344304; = p.S684* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 48/99 reads (48%) | catalogued as COSV60233273; called by muse, mutect2, varscan2
- TFAP2D | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV50429530; called by muse, mutect2, varscan2
- TG | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV55082520; called by muse, mutect2
- TLR10 | c.174C>A p.N58K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV58301045; called by muse, mutect2, varscan2
- WDR76 | c.1454G>A p.S485N | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV55478027; called by muse, mutect2, varscan2
- YWHAH | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV50708522; called by muse, mutect2, varscan2
- ZBTB24 | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs750596422, COSV57782498; called by muse, mutect2, varscan2
- ZNF302 | c.637C>G p.L213V (on ENST00000627982; = p.L134V on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV71063704; called by muse, mutect2, varscan2
- CDKL5 | c.1143C>A p.T381= | Silent (SNP) | VAF 73/206 reads (35%) | catalogued as COSV66111959; called by muse, mutect2, varscan2
- COL20A1 | c.3642C>T p.H1214= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1467474284, COSV58919894, COSV58920000; called by muse, mutect2, varscan2
- FAM124A | c.201C>T p.N67= (on ENST00000322475 / NM_001242312.2; = p.N103= on NM_145019.4) | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV54477739; called by muse, mutect2
- FAM83G | c.681G>A p.G227= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV58759615; called by muse, mutect2, varscan2
- GPR137B | c.795C>T p.S265= | Silent (SNP) | VAF 82/151 reads (54%) | catalogued as rs772538280, COSV63991241; called by muse, mutect2, varscan2
- IL23A | c.417T>C p.G139= | Silent (SNP) | VAF 71/158 reads (45%) | catalogued as COSV57336159; called by muse, mutect2, varscan2
- LILRB2 | c.930C>T p.S310= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs201113515, COSV58746436; called by muse, mutect2
- MLXIPL | c.1950G>T p.R650= | Silent (SNP) | VAF 52/228 reads (23%) | catalogued as COSV57668917; called by muse, mutect2, varscan2
- NPAP1 | c.93C>T p.D31= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs756871371, COSV61508440; called by muse, mutect2, varscan2
- PCDHA4 | c.1914C>T p.D638= | Silent (SNP) | VAF 57/141 reads (40%) | catalogued as rs781864694, COSV63539551; called by muse, mutect2, varscan2
- PRSS55 | c.885C>T p.I295= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as rs753193702, COSV60808667; called by muse, mutect2
- SBK2 | c.186C>T p.Y62= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs367873141, COSV60014745; called by muse, mutect2, varscan2
- SHKBP1 | c.120C>A p.I40= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV52541114; called by muse, mutect2, varscan2
- SSTR5 | c.477G>A p.A159= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs370872680; called by muse, mutect2, varscan2
- SYP | c.648C>T p.V216= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs1557102779, COSV54295765; called by muse, mutect2, varscan2
- C7orf66 | n.267G>A | RNA (SNP) | VAF 49/178 reads (28%) | catalogued as rs781619382; called by muse, mutect2, varscan2
- DCHS2 | n.6905C>T | RNA (SNP) | VAF 33/66 reads (50%) | catalogued as COSV61774618; called by muse, mutect2, varscan2
